Somatic mutation profile of tumor specimen TCGA-AA-3941-01A (aliquot TCGA-AA-3941-01A-01W-0995-10) from TCGA case TCGA-AA-3941, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 84.9 years (31,015 days).
Specimen TCGA-AA-3941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e46f777-a6bf-482e-b2cc-b6304eb7c4ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3941-10A (Blood Derived Normal), aliquot TCGA-AA-3941-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cbe952d-af2f-4f8c-af6a-690a1025efd8

The open-access MAF lists 117 somatic variants for this specimen: 95 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 20, Nonsense Mutation 4, Frame Shift Ins 3, RNA 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/36 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.467dup p.L156Ffs*11 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | catalogued as rs528833893; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TP53 | c.531_548del p.H178_S183del | In Frame Del (DEL) | VAF 76/86 reads (88%) | hotspot (GDC flag); called by mutect2, varscan2
- ABCA5 | c.4634G>A p.R1545H | Missense Mutation (SNP) | VAF 229/293 reads (78%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs370515109; called by muse, mutect2, varscan2
- ADAM23 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.315); catalogued as rs201146986; called by muse, mutect2, varscan2
- ADGRB2 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV57072604; called by muse, mutect2, varscan2
- ADGRV1 | c.4985G>A p.R1662H | Missense Mutation (SNP) | VAF 287/435 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs193222107, COSV67993512; called by muse, mutect2, varscan2
- ALG13 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 223/565 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371858098, COSV52638435; called by muse, mutect2, varscan2
- ANP32D | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 373/470 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56980751; called by muse, mutect2, varscan2
- ARHGAP15 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 430/752 reads (57%) | catalogued as rs763082124, COSV54517013; called by muse, mutect2, varscan2
- ARHGAP36 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV104370870, COSV99357116, COSV99357903; called by muse, mutect2
- ARHGEF5 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 433/495 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV50213796; called by muse, mutect2, varscan2
- ASAP2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747266776, COSV55632013; called by muse, mutect2, varscan2
- ASIC3 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52507533; called by muse, mutect2, varscan2
- ATP9A | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs199887924, COSV58766016; called by muse, mutect2, varscan2
- BMERB1 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 182/329 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757365966, COSV55509794; called by muse, mutect2, varscan2
- CBY2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60119502; called by muse, mutect2, varscan2
- CCDC141 | c.2512G>T p.D838Y | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV55377793, COSV55384771; called by muse, mutect2, varscan2
- CCR3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs567984457, COSV62462395; called by muse, mutect2, varscan2
- CDH2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as rs767296927; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1363G>A p.V455I (on ENST00000357886 / NM_001365728.1; = p.V441I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1568688092, COSV59427938; called by muse, mutect2, varscan2
- CEP41 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV56220672; called by muse, mutect2, varscan2
- CHRNA5 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55139481; called by muse, mutect2, varscan2
- CNTRL | c.6058C>G p.L2020V | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.425); catalogued as COSV53050136; called by muse, mutect2, varscan2
- CRHR1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs368605173; called by muse, mutect2, varscan2
- DAPK1 | c.868G>C p.A290P | Missense Mutation (SNP) | VAF 303/527 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); catalogued as COSV63791653; called by muse, mutect2, varscan2
- DST | c.21916G>A p.A7306T (on ENST00000361203 / NM_001374722.1; = p.A4979T on NM_015548.5) | Missense Mutation (SNP) | VAF 115/139 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771999169, COSV99758147; called by muse, mutect2, varscan2
- FADS3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs763877655, COSV53877971; called by muse, mutect2, varscan2
- FIZ1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV55608528; called by muse, varscan2
- GLRA3 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV56866054; called by muse, mutect2, varscan2
- GRIA1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 374/1495 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1194364279, COSV53597870; called by muse, mutect2, varscan2
- HOXD10 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1319651881, COSV50898946; called by muse, mutect2, varscan2
- IGHV3-21 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as rs782062113; called by muse, varscan2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2, varscan2
- INSRR | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs779010804; called by muse, mutect2, varscan2
- ITIH5 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs768283912, COSV53660329; called by muse, mutect2, varscan2
- KCNH7 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 177/308 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs971800856; called by muse, mutect2, varscan2
- KCNJ15 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60810899; called by muse, mutect2, varscan2
- KRT27 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 154/182 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs757452113, COSV56972575; called by muse, mutect2, varscan2
- LRRN3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as rs200291058; called by muse, mutect2, varscan2
- LRRTM1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54439946; called by muse, mutect2, varscan2
- MAP7D3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 143/838 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV60170099; called by muse, mutect2, varscan2
- MAST3 | c.2273_2275del p.S758_G759delins* | Nonsense Mutation (DEL) | VAF 4/13 reads (31%) | catalogued as COSV53223904; called by mutect2, varscan2
- MSN | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs371555667, COSV64303426, COSV64303855; called by muse, mutect2, varscan2
- MTF1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 124/483 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs984280990, COSV65988839; called by muse, mutect2, varscan2
- NME6 | c.235G>A p.G79R (on ENST00000415053; = p.G87R on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374032471; called by muse, mutect2, varscan2
- OR10J1 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs759770985, COSV71129202; called by muse, mutect2, varscan2
- PCDH7 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1298790860; called by muse, mutect2, varscan2
- PLA2G4C | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs145766964; called by muse, mutect2, varscan2
- PLCD1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs769966321, COSV52186663; called by muse, mutect2, varscan2
- PRAMEF1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs529027078; called by muse, mutect2, varscan2
- PRDM10 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 265/901 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1162981735, COSV58799915; called by muse, mutect2, varscan2
- PRDM9 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 147/213 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV57013456; called by muse, mutect2, varscan2
- PREX2 | c.4379C>A p.P1460Q | Missense Mutation (SNP) | VAF 241/360 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99909545; called by muse, mutect2, varscan2
- PRICKLE2 | c.1312T>A p.S438T (on ENST00000295902; = p.S382T on NM_198859.4) | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV55769229; called by muse, mutect2, varscan2
- PSME4 | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs780168392, COSV101122523; called by muse, mutect2, varscan2
- RBBP7 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 476/761 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs200756039, COSV58113228; called by muse, mutect2, varscan2
- RILPL2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV54913014; called by muse, mutect2
- RYR3 | c.4474G>A p.V1492I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs202225145, COSV66801159; ClinVar: uncertain significance; called by muse, varscan2
- SPACA4 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs143767613; called by muse, mutect2, varscan2
- SPDYE1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs200388629, COSV51669344; called by muse, mutect2
- SPRR3 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs1307211270; called by muse, mutect2, varscan2
- SPTB | c.4804G>A p.E1602K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180402020, COSV101072103; called by muse, mutect2, varscan2
- TMCO3 | c.737T>G p.I246S | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64808383; called by muse, mutect2, varscan2
- TMEM135 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 496/649 reads (76%) | catalogued as rs779626425, COSV59703498; called by muse, mutect2, varscan2
- TPO | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs753786141, COSV61103439; called by muse, mutect2, varscan2
- TPR | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66603146; called by muse, mutect2, varscan2
- VDAC3 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50081872, COSV99195136; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV60157785; called by muse, mutect2, varscan2
- ZNF778 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758123738; called by mutect2, varscan2
- ADAM29 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS9 | c.2627C>A p.P876H | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ARAP2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 175/564 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CD163 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COX19 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPA5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- GUCY2C | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 110/602 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HUWE1 | c.6494C>G p.A2165G | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGDCC3 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAD2L1BP | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- NTRK3 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP43 | c.141G>T p.W47C | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NUP43 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ODF2L | c.1454G>T p.S485I (on ENST00000317336; = p.S456I on NM_020729.3) | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OSBPL1A | c.2535+1G>A p.X845_splice (on ENST00000319481 / NM_080597.4; = p.X332_splice on NM_018030.4) | Splice Site (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLK4 | c.456T>G p.I152M | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM10 | c.993dup p.R332Afs*49 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- SYNE1 | c.3378G>A p.W1126* (on ENST00000367255 / NM_182961.4; = p.W1133* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | called by muse, varscan2
- SYNE1 | c.3199G>A p.D1067N (on ENST00000367255 / NM_182961.4; = p.D1074N on NM_033071.3) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, varscan2
- TOX4 | c.1458del p.Q486Hfs*16 | Frame Shift Del (DEL) | VAF 23/43 reads (53%) | called by mutect2, varscan2
- TRPM4 | c.1222_1231dup p.S411Nfs*5 | Frame Shift Ins (INS) | VAF 72/288 reads (25%) | called by mutect2, varscan2
- TTK | c.1800G>T p.M600I | Missense Mutation (SNP) | VAF 114/134 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- WDR35 | c.3086C>T p.A1029V (on ENST00000345530 / NM_001006657.2; = p.A1018V on NM_020779.4) | Missense Mutation (SNP) | VAF 197/445 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XKR6 | c.1304A>T p.E435V | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ASPM | c.8313C>T p.N2771= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as COSV54133804; called by muse, mutect2, varscan2
- CRYGA | c.120C>T p.S40= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs773733603, COSV58017835, COSV58018857; called by muse, mutect2, varscan2
- CTNNA3 | c.417G>A p.A139= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1204895034, COSV57720687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.4773C>T p.G1591= | Silent (SNP) | VAF 59/305 reads (19%) | catalogued as rs372171385; called by muse, mutect2, varscan2
- FAM117B | c.1188G>A p.T396= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs761574025, COSV57417200; called by muse, mutect2, varscan2
- FGD5 | c.2586T>G p.L862= | Silent (SNP) | VAF 45/198 reads (23%) | catalogued as rs1428466122, COSV53247356; called by muse, mutect2, varscan2
- FHOD3 | c.3918C>T p.D1306= (on ENST00000359247 / NM_001281739.3; = p.D1323= on NM_025135.5) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1279584551, COSV57173235; called by muse, mutect2, varscan2
- GORASP2 | c.945C>T p.L315= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV52202984; called by muse, mutect2, varscan2
- IGHM | c.1203C>T p.S401= | Silent (SNP) | VAF 84/185 reads (45%) | catalogued as rs782590938; called by muse, mutect2, varscan2
- ITIH5 | c.1806G>A p.R602= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2
- KCNK10 | c.828G>A p.T276= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs771445031, COSV56648676; called by muse, mutect2, varscan2
- LILRA1 | c.549T>C p.S183= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs781278891, COSV52182795; called by muse, mutect2, varscan2
- LRRTM1 | c.1206C>T p.H402= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, varscan2
- NBPF9 | c.549G>A p.L183= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs781958088; called by muse, mutect2, varscan2
- NIBAN2 | c.1839G>A p.S613= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs149383501; called by muse, varscan2
- PAPOLB | c.516A>C p.A172= | Silent (SNP) | VAF 94/148 reads (64%) | called by muse, mutect2, varscan2
- TAF2 | c.2586G>A p.Q862= | Silent (SNP) | VAF 80/444 reads (18%) | catalogued as COSV65419478; called by muse, mutect2, varscan2
- VPS13D | c.2871G>A p.A957= | Silent (SNP) | VAF 67/185 reads (36%) | catalogued as rs183276517, COSV50631308, COSV50656387; called by muse, mutect2, varscan2
- WT1 | c.987C>T p.S329= | Silent (SNP) | VAF 437/548 reads (80%) | catalogued as rs750018485, COSV60076764; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF746 | c.138G>A p.L46= | Silent (SNP) | VAF 97/157 reads (62%) | catalogued as COSV61408278; called by muse, mutect2, varscan2
- DCHS2 | n.1103C>A | RNA (SNP) | VAF 41/180 reads (23%) | catalogued as COSV59735788; called by muse, mutect2, varscan2
- IGHV1-12 | n.130T>A | RNA (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
